Somatic mutation profile of tumor specimen 0DIW87 from CCDI case PBBWGJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.6 years (962 days).
Specimen 0DIW87: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a760d8c6-f8a9-477c-b1f9-1f022eff310a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW6B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b13122b2-b83d-4fff-9bae-e52c2b526813

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPG | c.3262G>A p.G1088R | Missense Mutation (SNP) | VAF 216/472 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767239951, COSV61348288; called by muse, mutect2, varscan2
- CPT1B | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 74/694 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1453538929; called by muse, mutect2, varscan2
- FNIP2 | c.3085A>C p.S1029R | Missense Mutation (SNP) | VAF 210/455 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100032906; called by muse, mutect2, varscan2
- LRRC17 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 228/1060 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs371788242; called by muse, mutect2, varscan2
- EPPK1 | c.3562C>T p.L1188F | Missense Mutation (SNP) | VAF 430/669 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NDST4 | c.1178C>G p.S393* | Nonsense Mutation (SNP) | VAF 18/655 reads (3%) | called by muse, mutect2
- POU3F4 | c.1079A>T p.D360V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2
- PRMT5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 18/607 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- SLC43A2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 23/724 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ABCA13 | c.5598C>A p.P1866= | Silent (SNP) | VAF 197/870 reads (23%) | called by mutect2, varscan2
- KCNH4 | c.1323C>T p.G441= | Silent (SNP) | VAF 26/892 reads (3%) | called by muse, mutect2
- MS4A14 | c.348C>A p.I116= | Silent (SNP) | VAF 119/286 reads (42%) | called by muse, mutect2, varscan2
- MYH13 | c.1920C>T p.G640= | Silent (SNP) | VAF 130/749 reads (17%) | catalogued as rs747309262, COSV52830918; called by muse, mutect2, varscan2
- SERTAD1 | c.435C>T p.I145= | Silent (SNP) | VAF 146/323 reads (45%) | catalogued as rs747793204; called by muse, mutect2, varscan2
- TMEM221 | c.570C>G p.S190= | Silent (SNP) | VAF 68/316 reads (22%) | called by muse, mutect2, varscan2
